Somatic mutation profile of tumor specimen TCGA-CM-5349-01A (aliquot TCGA-CM-5349-01A-21D-1719-10) from TCGA case TCGA-CM-5349, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.1 years (24,867 days).
Specimen TCGA-CM-5349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b6ade46-ded3-4336-bc89-efda08722ae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5349-10A (Blood Derived Normal), aliquot TCGA-CM-5349-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b988483-a352-457a-bd45-1e27a3e78b07

The open-access MAF lists 112 somatic variants for this specimen: 77 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 30, Nonsense Mutation 6, RNA 4, Frame Shift Del 4, Intron 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 38/195 reads (19%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 89/199 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs377591770; called by muse, mutect2, varscan2
- ADAMTS17 | c.1439T>A p.F480Y | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as COSV51496634; called by muse, mutect2, varscan2
- ADARB1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs200222908, COSV100653574; called by muse, mutect2, varscan2
- AFF3 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780233607, COSV57876679; called by muse, mutect2, varscan2
- APC | c.4316del p.P1439Lfs*34 | Frame Shift Del (DEL) | VAF 37/162 reads (23%) | catalogued as COSV57382727; called by mutect2, pindel, varscan2
- BNC2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.066); catalogued as rs1191107098, COSV66140604; called by muse, mutect2
- CACNA1B | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1194337634, COSV53134475; called by muse, mutect2, varscan2
- CDC42BPB | c.4646G>T p.R1549L | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV100775131, COSV63475075; called by muse, mutect2, varscan2
- CDH7 | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1454779005, COSV59892035; called by muse, mutect2, varscan2
- CLCN6 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs761839015, COSV56738374; called by muse, mutect2, varscan2
- COL20A1 | c.3346C>A p.Q1116K | Missense Mutation (SNP) | VAF 98/578 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV58929549; called by muse, mutect2, varscan2
- COX5A | c.156T>G p.F52L | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV59280218; called by muse, mutect2, varscan2
- CPAMD8 | c.3716G>A p.R1239H (on ENST00000651564; = p.R1192H on NM_015692.5) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs371395530, COSV71596271; called by muse, mutect2, varscan2
- CSMD2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 45/218 reads (21%) | catalogued as COSV53974375; called by muse, mutect2, varscan2
- DAPK1 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200262418, COSV63792443; called by muse, mutect2, varscan2
- ETNPPL | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV56597022, COSV56597727, COSV56598085; called by muse, mutect2, varscan2
- FAF1 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as rs370024425, COSV100875461; called by muse, mutect2, varscan2
- FSTL5 | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60238003; called by muse, mutect2, varscan2
- GAD2 | c.1669T>C p.F557L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99392398, COSV99394183; called by muse, mutect2
- GRIA1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs564265256, COSV53625731; called by muse, mutect2, varscan2
- GRIK2 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100024197, COSV59763000; called by muse, mutect2, varscan2
- HIF3A | c.130G>A p.A44T (on ENST00000377670 / NM_152795.4; = p.S23= on NM_022462.4) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs960735275, COSV52205979; called by muse, mutect2, varscan2
- HMCN1 | c.11005C>T p.R3669* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as rs778136010, COSV54874869; called by muse, mutect2, varscan2
- HSD17B13 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56347533; called by muse, mutect2, varscan2
- IFI16 | c.1835G>A p.R612Q (on ENST00000295809 / NM_001364867.2; = p.R556Q on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs746538717, COSV55536518; called by mutect2, varscan2
- INPP5E | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1417022247, COSV65496795; called by muse, mutect2, varscan2
- JUP | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100159292; called by muse, mutect2, varscan2
- KCNB2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as rs866902223, COSV73051791; called by muse, mutect2
- KIF21B | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1364620614, COSV59768721; called by muse, mutect2, varscan2
- KMT2A | c.6661A>G p.R2221G | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV63293907; called by muse, mutect2, varscan2
- KRT78 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs911267505, COSV58854128; called by muse, mutect2, varscan2
- LVRN | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV63495995; called by muse, mutect2, varscan2
- MAGED2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as rs867098630, COSV54497627; called by muse, mutect2, varscan2
- MAP11 | c.477T>G p.D159E | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57588592; called by muse, mutect2, varscan2
- MDN1 | c.13916T>G p.L4639R | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65532333; called by muse, mutect2, varscan2
- MERTK | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs769030123, COSV54937180; called by muse, mutect2, varscan2
- MIEF2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs773059680, COSV59901483, COSV59902625; called by muse, mutect2, varscan2
- NFE2L1 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100671326; called by muse, mutect2, varscan2
- NOL6 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs139340786; called by muse, mutect2, varscan2
- NSA2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1244410682, COSV57189208; called by muse, mutect2, varscan2
- OR2A4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as COSV59576367; called by muse, mutect2, varscan2
- OR6N1 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58650875; called by muse, mutect2, varscan2
- PACSIN2 | c.1392G>A p.W464* | Nonsense Mutation (SNP) | VAF 65/170 reads (38%) | catalogued as COSV54324392; called by muse, mutect2, varscan2
- PCDHGA1 | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV65300550; called by muse, mutect2, varscan2
- PCDHGB3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53921139; called by mutect2, varscan2
- PFAS | c.19T>G p.F7V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs893279600, COSV58984128; called by muse, mutect2, varscan2
- PLCL1 | c.2209A>G p.K737E | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as rs1296768748, COSV70886837; called by muse, mutect2, varscan2
- RAB35 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as COSV57568802; called by muse, mutect2, varscan2
- RPL10 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV99185806; called by muse, mutect2, varscan2
- RYR3 | c.14138C>T p.T4713M (on ENST00000389232; = p.T4714M on NM_001036.6) | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101211892; called by muse, mutect2, varscan2
- S1PR2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs767074437, COSV58485951; called by muse, mutect2, varscan2
- SMG8 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs374585441; called by muse, mutect2, varscan2
- SOX17 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 187/338 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52028722; called by muse, mutect2, varscan2
- SV2A | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 121/477 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781926005, COSV64965949; called by muse, mutect2, varscan2
- TBCC | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55131276; called by mutect2, varscan2
- TCF7L2 | c.973C>T p.Q325* (on ENST00000355995 / NM_001367943.1; = p.Q302* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 40/210 reads (19%) | catalogued as COSV53347895, COSV53349157, COSV53351359; called by muse, mutect2, varscan2
- TK1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs375708499; called by muse, mutect2, varscan2
- TLL1 | c.2806T>G p.F936V | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99285926; called by muse, mutect2
- TMCC2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV63665541; called by muse, mutect2, varscan2
- TMEM140 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150916088; called by muse, mutect2, varscan2
- TRAK1 | c.1600C>T p.R534C (on ENST00000327628 / NM_001349247.2; = p.R476C on NM_014965.5) | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.606); catalogued as rs372408014; called by muse, mutect2, varscan2
- TRHDE | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.204); catalogued as rs1248388627, COSV53870687; called by muse, mutect2, varscan2
- TRIM45 | c.1161A>C p.E387D | Missense Mutation (SNP) | VAF 96/356 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV56715258; called by muse, mutect2, varscan2
- TTN | c.83972T>C p.V27991A (on ENST00000591111; = p.V20567A on NM_003319.4) | Missense Mutation (SNP) | VAF 55/216 reads (25%) | PolyPhen probably damaging (0.99); catalogued as COSV60416427; called by muse, mutect2, varscan2
- WNT9A | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.506); catalogued as rs779996471, COSV55297925; called by muse, mutect2, varscan2
- XIRP2 | c.2982T>A p.F994L (on ENST00000628543; = p.F1169L on NM_152381.6) | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54740981; called by muse, mutect2, varscan2
- ZNF772 | c.2_3insAGC p.M1? | Translation Start Site (INS) | VAF 57/320 reads (18%) | catalogued as COSV58410273, COSV58411920; called by mutect2, pindel, varscan2
- ZNF789 | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV58875574; called by muse, mutect2, varscan2
- CTCF | c.184_197del p.M62Gfs*10 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- EPC1 | c.2422_2423del p.V808Rfs*9 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | called by mutect2, pindel, varscan2
- GLS2 | c.929+2dup | Splice Region (INS) | VAF 46/212 reads (22%) | called by mutect2, pindel, varscan2
- IGHV4-28 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 127/539 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MIDEAS | c.1171_1212del p.G391_L404del | In Frame Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- MKI67 | c.2014dup p.T672Nfs*4 | Frame Shift Ins (INS) | VAF 138/638 reads (22%) | called by mutect2, pindel, varscan2
- TBCA | c.191_192delinsA p.I64Nfs*19 | Frame Shift Del (DEL) | VAF 58/229 reads (25%) | called by pindel, varscan2*
- AMMECR1 | c.258G>A p.S86= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV53321118; called by muse, mutect2
- CLK3 | c.888C>T p.I296= (on ENST00000395066 / NM_001130028.1; = p.I148= on NM_003992.4) | Silent (SNP) | VAF 53/210 reads (25%) | catalogued as rs1358718367, COSV61415308; called by muse, mutect2, varscan2
- CRMP1 | c.1107G>A p.A369= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs779301264, COSV61478481; called by muse, mutect2, varscan2
- CRP | c.357G>A p.E119= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV54815004; called by muse, mutect2, varscan2
- CUX2 | c.3633C>T p.T1211= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as rs921638433, COSV55651274; called by muse, mutect2, varscan2
- F8 | c.4983C>A p.V1661= | Silent (SNP) | VAF 168/624 reads (27%) | catalogued as rs782709406, COSV64278265; called by muse, mutect2, varscan2
- FUT1 | c.453G>A p.S151= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs750925379, COSV59570433; called by muse, mutect2, varscan2
- GABRR2 | c.1254C>T p.N418= | Silent (SNP) | VAF 105/416 reads (25%) | catalogued as rs370972483, COSV68764359; called by muse, mutect2, varscan2
- GRIA1 | c.141G>A p.S47= | Silent (SNP) | VAF 52/242 reads (21%) | catalogued as rs751940097, COSV53591420; called by muse, varscan2
- HK2 | c.546C>T p.G182= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as COSV99308461; called by muse, mutect2, varscan2
- KRT12 | c.69G>A p.S23= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs961985412, COSV52430931; called by muse, mutect2
- MEGF8 | c.3588C>T p.P1196= (on ENST00000251268 / NM_001271938.2; = p.P1129= on NM_001410.3) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs374616111, COSV52104987; called by muse, mutect2, varscan2
- MTUS2 | c.1977C>T p.D659= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs778158356, COSV70924679; called by muse, mutect2, varscan2
- NCKAP5 | c.3123G>A p.P1041= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as rs201870544; called by muse, mutect2, varscan2
- NT5DC3 | c.1584C>T p.P528= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as rs1313504332, COSV101230931, COSV67323408; called by muse, mutect2, varscan2
- OLFM4 | c.381T>C p.I127= | Silent (SNP) | VAF 73/311 reads (23%) | catalogued as COSV54581158; called by muse, mutect2, varscan2
- OLFML2A | c.1518A>G p.V506= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs1410389461, COSV56586126; called by muse, mutect2, varscan2
- PAM | c.2904C>T p.L968= (on ENST00000438793 / NM_001319943.1; = p.L969= on NM_000919.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs974983230, COSV57218553; called by muse, mutect2, varscan2
- PCDHB7 | c.1788G>A p.S596= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV50835152; called by muse, mutect2, varscan2
- PRKCQ | c.1695C>T p.F565= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs34060945; called by muse, mutect2, varscan2
- PTCHD3 | c.234G>A p.P78= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs752338563, COSV71257335; called by muse, mutect2, varscan2
- RAB5A | c.336A>G p.K112= | Silent (SNP) | VAF 100/454 reads (22%) | catalogued as COSV56086463; called by muse, mutect2, varscan2
- RADIL | c.330C>T p.Y110= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs575762308, COSV68201259, COSV68201630; called by muse, mutect2, varscan2
- RUNX2 | c.1203C>T p.T401= (on ENST00000371438; = p.T379= on NM_001015051.3) | Silent (SNP) | VAF 110/309 reads (36%) | catalogued as COSV61846831; called by muse, mutect2, varscan2
- RYR3 | c.6453G>T p.A2151= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV101211891, COSV66787409; called by muse, mutect2, varscan2
- SLC7A1 | c.1317G>A p.L439= | Silent (SNP) | VAF 156/437 reads (36%) | catalogued as rs1408742652, COSV66332187; called by muse, mutect2, varscan2
- TACR3 | c.417G>A p.T139= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as COSV59210029; called by muse, mutect2, varscan2
- TRRAP | c.2541G>A p.R847= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as COSV62856599; called by muse, mutect2, varscan2
- UGT3A1 | c.534A>G p.P178= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as COSV99954217; called by muse, mutect2, varscan2
- ZBTB9 | c.816T>C p.L272= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV67702487; called by muse, mutect2, varscan2
- KIR3DX1 | n.272G>A | RNA (SNP) | VAF 7/64 reads (11%) | catalogued as rs752917135, COSV55600991; called by muse, mutect2, varscan2
- MBNL1 | c.1111-1088C>G | Intron (SNP) | VAF 49/173 reads (28%) | catalogued as COSV56837185; called by muse, mutect2, varscan2
- MIR181A1 | n.74G>A | RNA (SNP) | VAF 64/204 reads (31%) | catalogued as rs759769471; called by muse, mutect2, varscan2
- TP73-AS1 | n.1411G>A | RNA (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- TP73-AS1 | n.1410A>C | RNA (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
